Surgical pathology report (de-identified scan), TCGA case TCGA-64-1679, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1679-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Right Lung Cancer

Source of Specimen(s):

- 1: Portion of 6th Rib
- 2: Level 9 Lymph Node
- 3: Level 4R Lymph Node
- 4: Right Upper Lobe
- 5: Level 4R Lymph Node
- 6: Pre-carinal Lymph Node
- 7: Level 7 Lymph Node

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled # 1, "portion of 6th rib"

Gross Description: Received fresh in a container labeled " patient name and medical number, portion of 6th rib". It consists of a fragment of rib

measuring 2.5 x 1.5 x 1.0 cm. There are no suspicious lesions or masses.

Representative sections are submitted in 1A following decalcification.

Source of Tissue: 2. Labeled # 2, "level 9 lymph node"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 9 lymph node". It consists of a single gray-tan

rubbery lymph node measuring 1.3 x 0.7 x 0.7 cm. No suspicious areas are identified. Submitted in toto in 2A.

Source of Tissue: 3. Labeled # 3, "level 4R lymph node"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 4R lymph node". It consists of two black potential

lymph nodes measuring respectively 0.5 and 0.7 cm in greatest dimension.

They are unremarkable and submitted in toto in 3A.

Source of Tissue: 4. Labeled # 4, "right upper lobe lung"

Frozen Section Diagnosis: 4FS- NO TUMOR SEEN .

Gross Description: Received fresh from O.R. for frozen section consultation in a container labeled " patient name and medical number, right

[page 2 of 3]
upper lobe lung". It consists of a 98-gram right upper lobe of lung measuring 12.4 x 9.5 x 5.5 cm. The bronchial margin was procured for frozen section and the residue is in 4FSA. The bronchial tree is opened and is free of lesions and masses. A few hilar and peribronchial nodes are found ranging from 0.4 up to 1.2 cm. The nodes are gray to black and unremarkable. The vascular margin is likewise unremarkable. The pleural surface is pink with a moderate amount of black anthracotic discoloration and central laterally there is a marked area of pleural puckering and thickening measuring 1.5 x 0.7 cm. Sections through this area disclose an ill-defined gray-tan firm mass measuring 2.0 x 1.8 x 1.8 cm. This tumor is 4.2 cm from the hilum/margin. Elsewhere the parenchyma is red, spongy and has no additional lesions or masses. Representative sections are submitted in 4A-E.

Designation of Sections: 4FSA- bronchial margin submitted for frozen section, 4A- vascular margins, 4B- hilar and peribronchial lymph nodes, 4C- tumor in relationship to pleura, 4D- tumor, 4E- lung tissue uninvolved

Source of Tissue: 5. Labeled # 5, "level 4R lymph node"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 4R lymph node". It consists of two black to red lymph nodes measuring respectively 0.7 and 1.9 cm in greatest dimension. The larger node is bisected and the smaller node is submitted as is. Both nodes are grossly unremarkable. Entirely submitted in 5A.

Source of Tissue: 6. Labeled # 6, "pre-carinal lymph node"

Frozen Section Diagnosis: 6FS- METASTATIC CANCER.

Gross Description: Received fresh from O.R. for frozen section consultation in a container labeled " patient name and medical number, pre-carinal lymph node". It consists of a single firm grayish black lymph node measuring 2.0 x 1.3 x 1.0 cm. Sections disclose a black to tan firm cut surface. Entirely submitted for frozen section and the residue is in 6FS.

Source of Tissue: 7. Labeled # 7, "level 7 lymph node"

Gross Description: Received fresh in a container labeled " patient name and medical number, level 7 lymph node". It consists of a single rubbery tan lymph node measuring 2.8 x 2.3 x 1.0 cm. Sections show a soft grayish black cut surface. Entirely submitted in 7A.

[page 3 of 3]
Final Diagnosis:

1. Portion of 6th rib, resection:- Bone and hypercellular bone marrow with trilineage hematopoiesis and lymphoid aggregates.
2. Level 9 lymph node, excision:
- One lymph node, no tumor seen (0/1).
3. Level 4R lymph node, excision:- Two lymph nodes, no tumor seen (0/2).
4. Right lung, upper lobe, lobectomy:
- Moderately differentiated adenocarcinoma with necrosis, 2.0 cm in greatest dimension grossly, with acinar growth pattern.
- Lymphovascular invasion is present.
- Tumor does not invade into visceral pleura.
- Bronchial and vascular resection margins are free of tumor.
- Seven hilar and peribronchial lymph nodes, no tumor seen (0/7).
5. Level 4R lymph node, excision:- Two lymph nodes, no tumor seen (0/2).
6. Pre-carinal lymph node, excision:
- One lymph node, positive for metastatic adenocarcinoma (1/1).
7. Level 7 lymph node, excision:
- One lymph node, no tumor seen (0/1).
- pT1 N2 Mx

Source: NCI Genomic Data Commons file 2157fe1f-bab4-4f43-b558-e7e1a1ae8a25 (TCGA-64-1679.DD4816B8-A99F-4F95-94B1-75B011509C2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).